Surgical pathology report (de-identified scan), TCGA case TCGA-73-4658, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-4658-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

*****Addendum*****

SPECIMEN(S): A. LEFT LOWER LUNG LOBE
B. HILAR MARGIN
C. 10L LYMPH NODE
D. 6TH RIB

CLINICAL HISTORY:

Left lung ca.

PRE-OPERATIVE DIAGNOSIS:

None

FROZEN SECTION DIAGNOSIS:

A. LEFT LOWER LUNG LOBE

Bronchial mucosa at margin of resection negative; however, there are dissociated tumor clusters within the bronchial lumen and in peripheral alveoli.

COMMENT: History of recurrent bronchioloalveolar carcinoma as per [REDACTED]

GROSS DESCRIPTION:

A. LEFT LOWER LUNG LOBE

Received fresh in a single container labelled [REDACTED] and designated "left lower lobe completion" and consists of a single lobe of lung weighing 256gm. The pleural surface ranges from tan red to black red and is rough with adhesions. The bronchial margin is removed and submitted en face in a single block labelled FSA1 for frozen section diagnosis. A large mass is palpable within the lung tissue and the pleura overlying this mass is inked black. The specimen is serially sectioned and an irregularly shaped tan yellow soft to focally firm tumor measuring 6.0x3.4x2.5cm. is identified. This tumor abuts the pleura focally in several places but does not appear to grossly invade through the pleura. One of the places where it is closest to the pleura is [REDACTED]

[page 2 of 4]
[REDACTED]

directly adjacent to the bronchial margin. The bulk of the tumor is 0.7cm. away from the nearest portion of the bronchial margin. Another smaller similar appearing tumor measuring 1.4cm. in diameter is noted approximately 0.5cm. away from the larger tumor. One anthracotic level 11 and one anthracotic level 12 peribronchial lymph node are identified. The bronchi are opened distally from the bronchial margin and the bronchial mucosa is uniformly tan without masses or lesions. The tumors do not grossly appear to arise from any major bronchus. The remainder of the cut surfaces are composed of tan red poorly aerated lung tissue. Representative portions of both normal appearing lung tissue and tumor are submitted to tissue procurement. Representative portions of the specimen are submitted per the code of sections.

FSA1: frozen section of bronchial margin en face

A2: vascular margins

A3: tumor abutting inked pleura adjacent to bronchial margin

A4-A9: tumor

A10: uninvolved lung adjacent to tumor

A11: uninvolved lung away from tumor

A12: one level 11 peribronchial lymph node

A13: one level 12 peribronchial lymph node

B. PYLOR MARGIN

Received in formalin in a single container labelled [REDACTED] and designated "pylor margin" and consists of a single portion of soft dark tan red tissue measuring 1.7x0.7x0.3cm. The specimen is bisected and the cut surfaces are unremarkable. The entire specimen is submitted in a single cassette labelled B1.

C. 10L LYMPH NODE

Received in formalin in a single container labelled [REDACTED] and designated "10L lymph node" and consists of a single anthracotic lymph node measuring 0.9x0.7x0.4cm. The specimen is bisected and the cut surfaces are unremarkable. The entire specimen is submitted in a single cassette labelled C1.

D. 6TH RIB

Received in formalin in a single container labelled [REDACTED] and designated "6th rib" and consists of three portions of bone appearing to be segments of rib ranging from 1.7x0.6x0.2cm. to 5.3x1.0x0.5cm. to 11.0x1.2x0.5cm. The resection margins on all portions are jagged and composed of unremarkable cortical and trabecular bone. The remainder of the cortical surfaces are smooth and tan grey. A representative portion of bone is removed by sawing and submitted after decalcification in a single cassette labelled D1.

[REDACTED]

DIAGNOSIS:

A. LUNG, LEFT LOWER LOBE, LOBECTOMY:

[REDACTED]

[page 3 of 4]
[REDACTED]

INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA OF LUNG IN A
BACKGROUND OF MULTIFOCAL BRONCHIOLOALVEOLAR CARCINOMA. SEE
TEMPLATE

-6.0x3.4x2.5cm -

-ANGIOLYMPHATIC INVASION IS PRESENT.

-VISCERAL PLEURAL MARGIN POSITIVE FOR TUMOR.

-BRONCHIAL MARGIN, NEGATIVE FOR TUMOR.

-TWO PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR METASTASIS

0/2).

B. HILAR MARGIN, EXCISION:

BRONCHIAL MARGIN, NEGATIVE FOR TUMOR BUT THE SURROUNDING
LUNG IS POSITIVE FOR ADENOCARCINOMA IN A BACKGROUND OF
BRONCHIOALVEOLAR CARCINOMA.

C. LYMPH NODE, 10L, EXCISION:

ONE LYMPH NODE, NEGATIVE FOR METASTASIS (0/1).

D. RIB, 6th, EXCISION:

BONE AND BONE MARROW WITH ORDERLY HEMOPOIESIS, NEGATIVE FOR
MALIGNANCY.

LUNG CANCER TEMPLATE

- | | |
|---------------------------------------|--|
| 1. Tumor type: | Adenocarcinoma |
| 2. Histologic Grade: | PD |
| 3. Tumor location: | Peripheral |
| 4. Tumor size: | 6.0x3.4x2.5cm |
| 5. Angiolymphatic invasion: | Present |
| 6. Perineural invasion: | absent |
| 7. Involvement of main stem bronchus: | Absent |
| 8. Bronchial margin: | Negative, see comment |
| 9. Visceral pleural margin: | Positive |
| 10. Hilar lymph nodes: | Negative (0/3) |
| 11. Insitu Carcinoma: | Absent |
| 12. Pathologic Stage: | pT2 pN1 MX |
| 13. Non-neoplastic lung: | Atelectasis; interstitial fibrosis; chronic inflammation |

COMMENT: In "B" although the bronchial margin is negative for carcinoma, dissociated clusters of tumor cells are seen within the bronchial lumen and within adjacent alveoli. Tumor cells are also noted in the perivascular soft tissue of the vascular margin. No tumor is seen intraluminally at the vascular margin.

[REDACTED]

[REDACTED]

[page 4 of 4]
ADDENDUM:

The pathologic stage should be pT2N0Mx to correspond to the negative lymph nodes (0/3).

~~Private~~

Source: NCI Genomic Data Commons file 8504c03f-912d-4510-b1b2-922d73a88866 (TCGA-73-4658.37BB6A7B-4F9E-4690-B904-4EEBC3189562.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).